Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6709, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6709-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy
Tumor site: Stomach
Tumor size: 5 x 0 x 6 cm
Tumor features: Exophytic (polypoid)
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Subserosa
Lymph nodes: 15/15 positive for metastasis (Greater and lesser omentum 15/15)
Lymphatic invasion: Not specified
Venous invasion: Absent
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 4425ad73-acf5-443c-bf4f-01ff6405f485 (TCGA-BR-6709.3E62B6AA-559F-40E1-9841-6DFBF13079D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).